CCDI case PBCACX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5c552396-4271-4d64-bea1-0532f29186fd

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,985 days).

Biospecimens (2 samples)
- Sample 0DRGED: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRGEW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
